Somatic mutation profile of tumor specimen HCM-CSHL-0369-D37-31A (aliquot HCM-CSHL-0369-D37-31A-11D-A78T-36) from HCMI case HCM-CSHL-0369-D37, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubulovillous adenoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage 0; Tumor grade: GX; Age at diagnosis: 62.2 years (22,734 days).
Specimen HCM-CSHL-0369-D37-31A: Sample type: Neoplasms of Uncertain and Unknown Behavior; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3288b01d-256f-4e06-9daa-ee73e024dfec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0369-D37-10A (Blood Derived Normal), aliquot HCM-CSHL-0369-D37-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c2635db-f923-4c15-a6d2-1a95ee0a4cdf

The open-access MAF lists 668 somatic variants for this specimen: 435 protein-altering or splice-affecting, 153 silent, 80 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 379, Silent 153, Intron 43, Nonsense Mutation 26, Splice Site 15, 3'UTR 10, 5'UTR 10, RNA 9, Frame Shift Del 8, Splice Region 6, 5'Flank 4, 3'Flank 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4463del p.L1488Yfs*19 | Frame Shift Del (DEL) | VAF 47/160 reads (29%) | catalogued as rs1114167577, COSV57389473; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- F11 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 51/244 reads (21%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.967); catalogued as rs763496524, CM035499, COSV53004761; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 10/256 reads (4%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2
- KRAS | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 116/278 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs1057519725, COSV55498939; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.1292G>T p.G431V (on ENST00000614293; = p.G401V on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs755157879; called by muse, mutect2
- ABCC10 | c.3540C>A p.N1180K (on ENST00000372530 / NM_001198934.2; = p.N1152K on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as rs770171491; called by muse, mutect2
- ACACB | c.394G>T p.G132C | Missense Mutation (SNP) | VAF 34/293 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.286); catalogued as COSV58139897; called by muse, mutect2, varscan2
- ACADL | c.547G>A p.G183R | Missense Mutation (SNP) | VAF 32/234 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52053486; called by muse, mutect2, varscan2
- ADAMTS10 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 41/266 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs1401325722; called by muse, mutect2, varscan2
- ADCK5 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 11/164 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as rs782782811, COSV100450557; called by muse, mutect2
- ADIPOQ | c.13G>T p.G5* | Nonsense Mutation (SNP) | VAF 27/160 reads (17%) | catalogued as COSV100292116; called by muse, mutect2, varscan2
- AHNAK2 | c.12067G>T p.A4023S | Missense Mutation (SNP) | VAF 165/815 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); catalogued as rs200136053, COSV100317552; called by muse, mutect2, varscan2
- ALDH8A1 | c.1272G>T p.W424C | Missense Mutation (SNP) | VAF 78/448 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1243708697; called by muse, mutect2, varscan2
- AMER3 | c.1011G>T p.R337S | Missense Mutation (SNP) | VAF 47/230 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV58464915, COSV58466651; called by muse, mutect2, varscan2
- ANK3 | c.514-1G>T p.X172_splice | Splice Site (SNP) | VAF 45/222 reads (20%) | catalogued as COSV55085635, COSV99782194; called by muse, mutect2, varscan2
- ANKFN1 | c.1213C>T p.R405W | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.723); catalogued as rs758805882, COSV59444149; called by muse, mutect2, varscan2
- ARHGAP22 | c.2053G>T p.G685* | Nonsense Mutation (SNP) | VAF 63/374 reads (17%) | catalogued as COSV99984179; called by muse, mutect2, varscan2
- ARHGEF10 | c.3326G>A p.G1109D (on ENST00000398564; = p.G1084D on NM_014629.4) | Missense Mutation (SNP) | VAF 97/519 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1407678176; called by muse, mutect2, varscan2
- ATM | c.3719A>G p.N1240S | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.143); catalogued as rs1555092536; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP1A4 | c.2394G>A p.M798I | Missense Mutation (SNP) | VAF 48/334 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV63625497; called by muse, varscan2
- ATP5F1D | c.479A>G p.N160S | Missense Mutation (SNP) | VAF 165/343 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs372801460; called by muse, mutect2, varscan2
- AXDND1 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0.286); catalogued as rs200125774, COSV62639986; called by muse, mutect2, varscan2
- BAP1 | c.588G>T p.W196C | Missense Mutation (SNP) | VAF 129/715 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.756); catalogued as rs1193212091, CM134973, COSV56231737; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCO1 | c.353C>A p.P118H | Missense Mutation (SNP) | VAF 87/529 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99257934; called by muse, mutect2, varscan2
- BRCA2 | c.8257C>T p.L2753F | Missense Mutation (SNP) | VAF 65/204 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.265); catalogued as COSV66452544; called by muse, mutect2, varscan2
- BTNL8 | c.428C>T p.T143M | Missense Mutation (SNP) | VAF 39/241 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs749688648, COSV99180609; called by muse, mutect2, varscan2
- CACNA1H | c.4560C>A p.D1520E | Missense Mutation (SNP) | VAF 115/323 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs1301892178, COSV100673663; called by muse, mutect2, varscan2
- CDC73 | c.545T>A p.I182N | Missense Mutation (SNP) | VAF 77/405 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66469369; called by muse, mutect2, varscan2
- CIC | c.766-1G>C p.X256_splice | Splice Site (SNP) | VAF 106/860 reads (12%) | catalogued as COSV50579167, COSV50650836; called by muse, mutect2, varscan2
- CLCNKB | c.1621G>A p.G541S | Missense Mutation (SNP) | VAF 111/664 reads (17%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs561674468, COSV65162071; called by muse, mutect2, varscan2
- CLEC4G | c.167C>A p.A56D | Missense Mutation (SNP) | VAF 35/277 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100183756; called by muse, mutect2, varscan2
- CNTN1 | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 70/386 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs144047921; called by muse, varscan2
- COL22A1 | c.2966C>T p.P989L | Missense Mutation (SNP) | VAF 92/247 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.842); catalogued as rs370576971; called by muse, mutect2, varscan2
- COL5A3 | c.812G>T p.W271L | Missense Mutation (SNP) | VAF 41/292 reads (14%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs749331493; called by muse, mutect2, varscan2
- CPT1C | c.1034G>C p.G345A | Missense Mutation (SNP) | VAF 33/317 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.115); catalogued as rs1365388312; called by muse, mutect2, varscan2
- CTTN | c.1648C>A p.Q550K | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV57230263; called by muse, mutect2, varscan2
- CUEDC1 | c.347G>A p.R116K | Missense Mutation (SNP) | VAF 34/234 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1442150426; called by muse, mutect2, varscan2
- CUL4A | c.1880C>T p.T627M (on ENST00000375440 / NM_001008895.4; = p.T527M on NM_003589.3) | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760636923, COSV58371794; called by muse, mutect2, varscan2
- CXorf21 | c.219C>A p.S73R | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.344); catalogued as rs373780978; called by muse, mutect2, varscan2
- DGKI | c.2062C>T p.P688S | Missense Mutation (SNP) | VAF 100/630 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99935948, COSV99937040; called by muse, mutect2, varscan2
- DMGDH | c.1408C>T p.R470* | Nonsense Mutation (SNP) | VAF 253/755 reads (34%) | catalogued as rs745676529, COSV54861370; called by muse, mutect2, varscan2
- DNAH17 | c.178G>A p.G60S | Missense Mutation (SNP) | VAF 21/385 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); catalogued as rs374692194; called by muse, mutect2
- DRP2 | c.1460G>A p.R487H | Missense Mutation (SNP) | VAF 62/260 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745315795, COSV100871981; called by muse, varscan2
- ELMOD1 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.204); catalogued as rs763943002; called by muse, mutect2, varscan2
- ETV2 | c.29C>A p.S10Y | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV52897526; called by muse, mutect2, varscan2
- FAM174B | c.148G>C p.G50R | Missense Mutation (SNP) | VAF 47/272 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.052); catalogued as rs1193140143; called by muse, mutect2, varscan2
- FAM90A1 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 355/1393 reads (25%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.723); catalogued as rs374455262; called by muse, mutect2, varscan2
- FAT3 | c.5426C>T p.A1809V | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99965060; called by muse, varscan2
- FLRT2 | c.1024C>A p.P342T | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58141797; called by muse, mutect2, varscan2
- FPR3 | c.456C>A p.F152L | Missense Mutation (SNP) | VAF 16/269 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100200508; called by muse, mutect2
- FRMPD1 | c.2972C>T p.P991L | Missense Mutation (SNP) | VAF 73/362 reads (20%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.007); catalogued as rs1252568210; called by muse, mutect2, varscan2
- GABRA4 | c.1225C>A p.H409N | Missense Mutation (SNP) | VAF 53/266 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV51932770; called by muse, mutect2, varscan2
- GATA3 | c.123C>A p.Y41* | Nonsense Mutation (SNP) | VAF 20/702 reads (3%) | catalogued as COSV60516443; called by muse, mutect2
- GGT5 | c.712G>T p.G238W | Missense Mutation (SNP) | VAF 83/432 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99571366; called by muse, mutect2, varscan2
- GIMAP8 | c.1657G>T p.G553* | Nonsense Mutation (SNP) | VAF 30/219 reads (14%) | catalogued as COSV56233860; called by muse, mutect2, varscan2
- GNL3L | c.752C>A p.T251N | Missense Mutation (SNP) | VAF 78/423 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV60577538; called by muse, mutect2, varscan2
- GOLGA6C | c.682G>T p.E228* | Nonsense Mutation (SNP) | VAF 142/1600 reads (9%) | catalogued as COSV56035860; called by muse, mutect2
- GPT2 | c.1093G>T p.G365C | Missense Mutation (SNP) | VAF 71/429 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV100413013; called by muse, mutect2, varscan2
- GTF2F1 | c.793G>T p.D265Y | Missense Mutation (SNP) | VAF 63/508 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1034936279; called by muse, mutect2, varscan2
- HKDC1 | c.2726G>T p.R909M | Missense Mutation (SNP) | VAF 11/240 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100664346; called by muse, mutect2
- HLA-DQA2 | c.29G>C p.G10A | Missense Mutation (SNP) | VAF 69/423 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV99059277; called by muse, mutect2, varscan2
- HMCN1 | c.1562C>T p.P521L | Missense Mutation (SNP) | VAF 78/260 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750199952, COSV99623606; called by muse, mutect2, varscan2
- HNMT | c.571C>G p.P191A | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.436); catalogued as COSV54511022; called by muse, mutect2
- ICE1 | c.1669G>T p.G557* | Nonsense Mutation (SNP) | VAF 50/254 reads (20%) | catalogued as COSV56828005; called by muse, mutect2, varscan2
- IFT22 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 41/293 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs772768460; called by muse, mutect2, varscan2
- IQCK | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 77/226 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750703451, COSV57521319; called by muse, mutect2
- IRX5 | c.335G>C p.G112A | Missense Mutation (SNP) | VAF 61/390 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV100315616; called by muse, mutect2, varscan2
- ITK | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 91/493 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.887); catalogued as rs201892355; called by muse, mutect2, varscan2
- ITK | c.158G>T p.G53V | Missense Mutation (SNP) | VAF 130/381 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101439852, COSV70065503; called by muse, mutect2, varscan2
- KLHL17 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 38/203 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs746924238; called by muse, mutect2, varscan2
- KY | c.1493G>T p.G498V | Missense Mutation (SNP) | VAF 35/216 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.441); catalogued as COSV71016574; called by muse, mutect2, varscan2
- LAIR1 | c.154C>A p.P52T | Missense Mutation (SNP) | VAF 54/472 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV57309556; called by muse, mutect2, varscan2
- LAS1L | c.1372G>A p.A458T | Missense Mutation (SNP) | VAF 79/247 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs750728472; called by muse, mutect2, varscan2
- LNX1 | c.1888C>T p.P630S (on ENST00000263925 / NM_001126328.3; = p.P534S on NM_032622.2) | Missense Mutation (SNP) | VAF 71/481 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as rs766927614; called by muse, mutect2, varscan2
- LRRC10B | c.92G>T p.R31L | Missense Mutation (SNP) | VAF 98/322 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as rs1238259152; called by muse, mutect2, varscan2
- LRRN4CL | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 71/468 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.169); catalogued as rs1565140470; called by muse, mutect2, varscan2
- MAP3K4 | c.4096G>A p.G1366R | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100815616, COSV62329900; called by muse, mutect2
- MAST3 | c.2146G>A p.V716I | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs766988885; called by muse, varscan2
- ME3 | c.646G>T p.G216* | Nonsense Mutation (SNP) | VAF 34/233 reads (15%) | catalogued as COSV60165429; called by muse, mutect2, varscan2
- MEF2B | c.358G>T p.G120W | Missense Mutation (SNP) | VAF 55/359 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV50769487; called by muse, mutect2, varscan2
- MICAL3 | c.4904C>A p.A1635E | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.131); catalogued as rs775830864; called by muse, mutect2, varscan2
- MTG2 | c.1027G>A p.V343I | Missense Mutation (SNP) | VAF 81/244 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.03); catalogued as rs146666461; called by muse, mutect2, varscan2
- MUC5AC | c.13446C>A p.S4482R | Missense Mutation (SNP) | VAF 122/836 reads (15%) | SIFT deleterious (0.02); catalogued as rs1554928988; called by muse, varscan2
- MYO9B | c.6182G>A p.R2061Q | Missense Mutation (SNP) | VAF 84/176 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs756634070; called by muse, mutect2, varscan2
- NCAM2 | c.2393C>G p.T798R | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1191821223; called by muse, mutect2, varscan2
- NCOR2 | c.3898C>T p.P1300S | Missense Mutation (SNP) | VAF 31/241 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV62298111; called by muse, mutect2, varscan2
- NR4A3 | c.599C>A p.P200H | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs1047114588; called by muse, mutect2, varscan2
- OLFML2A | c.1711C>T p.R571W | Missense Mutation (SNP) | VAF 116/344 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs369965570, COSV56585775, COSV99992653; called by muse, mutect2, varscan2
- OR14K1 | c.151C>A p.H51N | Missense Mutation (SNP) | VAF 49/296 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV99032175; called by muse, mutect2, varscan2
- OR1L1 | c.905A>T p.Y302F (on ENST00000373686; = p.Y252F on NM_001005236.3) | Missense Mutation (SNP) | VAF 40/268 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs779657692; called by muse, mutect2, varscan2
- PALD1 | c.1465C>A p.L489M | Missense Mutation (SNP) | VAF 45/228 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.878); catalogued as rs1272066840, COSV54977900; called by muse, mutect2, varscan2
- PCDHA10 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 257/368 reads (70%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as rs1250461159, COSV56479266; called by muse, mutect2, varscan2
- PCDHA13 | c.1786G>A p.A596T | Missense Mutation (SNP) | VAF 211/595 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1313975286, COSV56487940; called by muse, mutect2, varscan2
- PCDHAC2 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 12/280 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); catalogued as rs868948639; called by muse, mutect2
- PIEZO2 | c.2960C>T p.T987I | Missense Mutation (SNP) | VAF 118/334 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1323885459; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLCB4 | c.2962G>T p.G988* | Nonsense Mutation (SNP) | VAF 41/229 reads (18%) | catalogued as COSV53819214; called by muse, mutect2, varscan2
- PLEKHG7 | c.1126G>A p.V376M | Missense Mutation (SNP) | VAF 43/207 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.358); catalogued as rs370641297, COSV60821279; called by muse, mutect2, varscan2
- PLEKHH2 | c.3257G>A p.R1086H | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775706144; called by muse, mutect2, varscan2
- PPP5C | c.1183C>T p.R395C | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as COSV50141930; called by muse, mutect2, varscan2
- PRF1 | c.984G>A p.W328* | Nonsense Mutation (SNP) | VAF 87/436 reads (20%) | catalogued as rs1349520883; called by muse, mutect2, varscan2
- PRPH | c.1058G>A p.G353D | Missense Mutation (SNP) | VAF 88/610 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as rs777418543, COSV57678619; called by muse, mutect2, varscan2
- PTK2B | c.2118G>T p.E706D | Missense Mutation (SNP) | VAF 29/203 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.071); catalogued as COSV100593714; called by muse, mutect2, varscan2
- RAB40A | c.144del p.I49Sfs*15 | Frame Shift Del (DEL) | VAF 92/540 reads (17%) | catalogued as rs927777392; called by mutect2, pindel, varscan2
- RERGL | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 20/158 reads (13%) | catalogued as rs200801104, COSV57461607; called by muse, mutect2, varscan2
- RGS19 | c.465G>A p.V155= | Splice Region (SNP) | VAF 32/111 reads (29%) | catalogued as COSV58657885; called by muse, mutect2, varscan2
- RGS19 | c.307G>A p.V103M | Missense Mutation (SNP) | VAF 27/404 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.314); catalogued as rs761093596; called by muse, mutect2
- RIMBP3 | c.2668C>A p.P890T | Missense Mutation (SNP) | VAF 111/836 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs780326851; called by muse, mutect2, varscan2
- RPL36A | c.108G>C p.Q36H | Missense Mutation (SNP) | VAF 62/165 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV100864959; called by muse, mutect2, varscan2
- RPS6KA4 | c.2252C>T p.P751L | Missense Mutation (SNP) | VAF 44/236 reads (19%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.027); catalogued as rs1382584499, COSV53707678; called by muse, mutect2, varscan2
- SALL2 | c.1583C>A p.P528H | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100444382; called by muse, mutect2, varscan2
- SBNO1 | c.3847C>T p.R1283C (on ENST00000420886; = p.R1282C on NM_018183.5) | Missense Mutation (SNP) | VAF 20/297 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1223604052, COSV57347007; called by muse, mutect2
- SCML4 | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 49/271 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1335530161; called by muse, mutect2, varscan2
- SCN8A | c.1150G>A p.G384R | Missense Mutation (SNP) | VAF 73/267 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61976013; called by muse, mutect2, varscan2
- SDK1 | c.2604G>T p.V868= | Splice Region (SNP) | VAF 20/202 reads (10%) | catalogued as rs1312144441; called by muse, mutect2
- SF3A1 | c.31C>A p.P11T | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated, low confidence (0.31); PolyPhen possibly damaging (0.908); catalogued as rs762353088; called by muse, mutect2, varscan2
- SHANK1 | c.6391G>T p.A2131S | Missense Mutation (SNP) | VAF 49/462 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.049); catalogued as rs757609780, COSV53259950; called by muse, mutect2, varscan2
- SIGLEC1 | c.3475C>A p.R1159S | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.746); catalogued as rs751425613, COSV52465843; called by muse, mutect2
- SLC2A1 | c.158G>T p.G53V | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.217); catalogued as rs796053246; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC30A8 | c.1070A>C p.Q357P | Missense Mutation (SNP) | VAF 48/277 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.884); catalogued as COSV69970498; called by muse, mutect2, varscan2
- SLC6A12 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 62/269 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs759619929, COSV100675120; called by muse, mutect2, varscan2
- SLC6A13 | c.769G>T p.G257W | Missense Mutation (SNP) | VAF 46/524 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58255230; called by muse, mutect2
- SLFN11 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 74/212 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs777285142, COSV57697771, COSV57697775; called by muse, mutect2, varscan2
- SOX6 | c.2312C>G p.P771R (on ENST00000528429 / NM_001145819.2; = p.P744R on NM_017508.3) | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57045917; called by muse, mutect2
- STAB2 | c.4124G>T p.G1375V | Missense Mutation (SNP) | VAF 50/468 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.381); catalogued as COSV66336261; called by muse, mutect2, varscan2
- TAF1L | c.2671A>G p.T891A | Missense Mutation (SNP) | VAF 97/513 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.45); catalogued as rs769607898; called by muse, mutect2, varscan2
- TANC1 | c.884G>A p.G295D | Missense Mutation (SNP) | VAF 13/407 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as rs1199504077; called by muse, mutect2
- THBS3 | c.400A>G p.R134G | Missense Mutation (SNP) | VAF 108/572 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs746128823; called by muse, mutect2, varscan2
- TMC1 | c.2177C>T p.A726V | Missense Mutation (SNP) | VAF 124/383 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs573874378, COSV52769526; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMEM145 | c.877G>A p.V293M | Missense Mutation (SNP) | VAF 73/490 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs771462112; called by muse, mutect2, varscan2
- TRPC7 | c.966C>A p.F322L | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV61454915; called by muse, mutect2, varscan2
- TULP1 | c.498G>T p.R166S | Missense Mutation (SNP) | VAF 104/630 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV57693264; called by muse, mutect2, varscan2
- USP48 | c.2186G>C p.R729T | Missense Mutation (SNP) | VAF 85/256 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as COSV57613775; called by muse, mutect2, varscan2
- WAS | c.1118C>T p.P373L | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs1181105100; called by muse, mutect2, varscan2
- WBP11 | c.1462C>G p.P488A | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated, low confidence (0.49); PolyPhen probably damaging (0.986); catalogued as COSV99660628; called by mutect2, varscan2
- ZNF106 | c.3961C>A p.P1321T | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV99782267; called by muse, mutect2, varscan2
- ZNF706 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 51/385 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as COSV60863461; called by muse, mutect2, varscan2
- ZNF837 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 91/691 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.848); catalogued as rs972389511; called by muse, mutect2, varscan2
- A1BG | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 102/750 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- AARS1 | c.2400+1G>T p.X800_splice | Splice Site (SNP) | VAF 105/555 reads (19%) | called by muse, mutect2, varscan2
- AATK | c.1057G>T p.E353* (on ENST00000326724 / NM_001080395.3; = p.E250* on NM_004920.2) | Nonsense Mutation (SNP) | VAF 12/51 reads (24%) | called by muse, mutect2, varscan2
- ABCF3 | c.1445A>G p.D482G | Missense Mutation (SNP) | VAF 108/302 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- ABO | c.649G>T p.D217Y | Missense Mutation (SNP) | VAF 155/828 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ACTN2 | c.1210G>T p.E404* | Nonsense Mutation (SNP) | VAF 136/810 reads (17%) | called by muse, mutect2, varscan2
- ACTR2 | c.1109A>T p.N370I | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.116); called by muse, mutect2
- ADAD1 | c.1488T>A p.S496R | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ADCK1 | c.1511G>T p.G504V | Missense Mutation (SNP) | VAF 49/279 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ADGB | c.4481G>T p.G1494V | Missense Mutation (SNP) | VAF 86/524 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ADGRB2 | c.3002C>T p.A1001V | Missense Mutation (SNP) | VAF 73/179 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADGRD2 | c.61C>A p.P21T | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADGRF4 | c.2026G>T p.A676S | Missense Mutation (SNP) | VAF 63/365 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- AEBP1 | c.3413C>T p.A1138V | Missense Mutation (SNP) | VAF 94/613 reads (15%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- AK9 | c.-10A>C | Splice Region (SNP) | VAF 24/125 reads (19%) | called by muse, mutect2, varscan2
- AKR1C2 | c.541G>T p.G181W | Missense Mutation (SNP) | VAF 41/267 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALX4 | c.33G>T p.E11D | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMBN | c.379C>T p.L127F | Missense Mutation (SNP) | VAF 155/529 reads (29%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- AMBRA1 | c.2653C>T p.Q885* (on ENST00000458649 / NM_001367468.1; = p.Q795* on NM_017749.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 70/214 reads (33%) | called by mutect2, varscan2
- AMER2 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 12/335 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.261); called by muse, mutect2
- AMY2B | c.316-1G>T p.X106_splice | Splice Site (SNP) | VAF 55/323 reads (17%) | called by muse, mutect2, varscan2
- ANAPC1 | c.4627C>A p.H1543N | Missense Mutation (SNP) | VAF 45/346 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ANK2 | c.87T>A p.S29= | Splice Region (SNP) | VAF 77/418 reads (18%) | called by muse, mutect2, varscan2
- ANK2 | c.9733C>G p.P3245A | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- ANKRD6 | c.226C>A p.Q76K | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- APBB1IP | c.1148T>C p.V383A | Missense Mutation (SNP) | VAF 46/231 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- ARHGAP35 | c.2495G>T p.R832L | Missense Mutation (SNP) | VAF 45/463 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.702); called by muse, mutect2
- ARHGEF17 | c.5519T>A p.L1840H | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- ARSJ | c.1006G>T p.G336W | Missense Mutation (SNP) | VAF 45/218 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASXL1 | c.4187T>G p.V1396G | Missense Mutation (SNP) | VAF 49/354 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); called by muse, mutect2
- BAHCC1 | c.1477T>A p.Y493N | Missense Mutation (SNP) | VAF 50/369 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- BICRA | c.3581C>T p.A1194V | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); called by muse, mutect2
- BPIFC | c.609T>G p.I203M | Missense Mutation (SNP) | VAF 14/350 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2
- BRCA1 | c.1228G>T p.A410S | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- C12orf54 | c.133C>A p.Q45K | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2
- C1QC | c.172G>C p.G58R | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C2CD3 | c.884C>T p.T295I | Missense Mutation (SNP) | VAF 32/404 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.272); called by muse, mutect2
- CCDC157 | c.2054C>T p.P685L | Missense Mutation (SNP) | VAF 103/592 reads (17%) | SIFT tolerated, low confidence (0.46); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- CCDC89 | c.630G>T p.E210D | Missense Mutation (SNP) | VAF 66/343 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CD163L1 | c.2684C>T p.S895F | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD83 | c.254C>A p.P85H | Missense Mutation (SNP) | VAF 90/485 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- CDC20 | c.71C>A p.P24H | Missense Mutation (SNP) | VAF 119/469 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CDH22 | c.698T>G p.L233R | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- CDH7 | c.271del p.A91Qfs*85 | Frame Shift Del (DEL) | VAF 53/271 reads (20%) | called by mutect2, pindel, varscan2
- CDIN1 | c.150A>G p.K50= | Splice Region (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- CDK11A | c.2059C>A p.L687I (on ENST00000378633 / NM_001313896.2; = p.L684I on NM_024011.4) | Missense Mutation (SNP) | VAF 41/230 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CELSR3 | c.6877G>T p.G2293* | Nonsense Mutation (SNP) | VAF 24/149 reads (16%) | called by muse, mutect2, varscan2
- CENPH | c.664G>T p.G222W | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFAP46 | c.7075del p.S2359Lfs*18 | Frame Shift Del (DEL) | VAF 78/198 reads (39%) | called by mutect2, pindel, varscan2
- CLCNKA | c.434G>C p.G145A | Missense Mutation (SNP) | VAF 62/524 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- CLEC2B | c.208C>A p.L70I | Missense Mutation (SNP) | VAF 42/292 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CMYA5 | c.8209C>T p.H2737Y | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CNEP1R1 | c.201C>A p.H67Q (on ENST00000427478 / NM_001281789.1; = p.H84Q on NM_153261.5) | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CNTNAP2 | c.3310C>A p.H1104N | Missense Mutation (SNP) | VAF 65/666 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- COL11A2 | c.2305G>T p.G769C (on ENST00000341947 / NM_080680.3; = p.G662C on NM_080679.2) | Missense Mutation (SNP) | VAF 134/718 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL18A1 | c.3975_3983del p.X1325_splice (on ENST00000359759 / NM_130444.3; = p.X1090_splice on NM_030582.4) | Splice Site (DEL) | VAF 32/98 reads (33%) | called by mutect2, pindel, varscan2
- COL3A1 | c.4129G>T p.A1377S | Missense Mutation (SNP) | VAF 120/301 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- COL5A1 | c.2241G>T p.L747F | Missense Mutation (SNP) | VAF 70/382 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- COLQ | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 74/443 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- COX17 | c.158A>G p.K53R | Missense Mutation (SNP) | VAF 28/210 reads (13%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- CRTC2 | c.191G>A p.S64N | Missense Mutation (SNP) | VAF 36/260 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CTAG2 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 332/634 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CUL5 | c.1055G>T p.S352I | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CXCL6 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 64/325 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- CYB5R3 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 99/569 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYP27A1 | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 19/322 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- CYP2J2 | c.1193G>T p.G398V | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2
- DAB2IP | c.712G>T p.D238Y (on ENST00000408936; = p.D210Y on NM_032552.3) | Missense Mutation (SNP) | VAF 57/349 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DENND2D | c.150del p.Q51Sfs*24 | Frame Shift Del (DEL) | VAF 22/171 reads (13%) | called by mutect2, pindel, varscan2
- DGKG | c.734G>T p.W245L | Missense Mutation (SNP) | VAF 49/284 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- DHRS1 | c.617C>A p.A206E | Missense Mutation (SNP) | VAF 41/354 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DMD | c.5185C>A p.P1729T | Missense Mutation (SNP) | VAF 16/448 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.205); called by muse, mutect2
- DNAH10 | c.2216A>G p.K739R (on ENST00000409039; = p.K678R on NM_207437.3) | Missense Mutation (SNP) | VAF 42/399 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- DYNC2H1 | c.2290G>T p.G764C | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EEF2K | c.1087A>G p.R363G | Missense Mutation (SNP) | VAF 65/286 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- EHMT1 | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EIF2S2 | c.337C>G p.P113A | Missense Mutation (SNP) | VAF 99/279 reads (35%) | SIFT tolerated (0.76); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ENPP2 | c.890A>G p.D297G | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.924); called by muse, mutect2
- EPHA3 | c.1496T>A p.L499H | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ESYT2 | c.2721G>T p.W907C (on ENST00000613624; = p.W831C on NM_020728.3) | Missense Mutation (SNP) | VAF 30/348 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.278); called by muse, mutect2
- FAM120A | c.2114C>G p.P705R | Missense Mutation (SNP) | VAF 62/349 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- FAM120A | c.2894G>T p.G965V | Missense Mutation (SNP) | VAF 82/413 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM131C | c.127G>T p.V43F | Missense Mutation (SNP) | VAF 69/465 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- FAM83G | c.880G>C p.E294Q | Missense Mutation (SNP) | VAF 56/297 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FANCA | c.1841C>T p.P614L | Missense Mutation (SNP) | VAF 20/526 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAT1 | c.6668C>A p.P2223H | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBXO10 | c.1079C>A p.P360H | Missense Mutation (SNP) | VAF 62/223 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- FGD6 | c.1828G>A p.D610N | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FIG4 | c.2468A>G p.Q823R | Missense Mutation (SNP) | VAF 73/385 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- FIGNL1 | c.134G>T p.W45L | Missense Mutation (SNP) | VAF 33/271 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- FLNC | c.6083C>A p.P2028H | Missense Mutation (SNP) | VAF 108/835 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLNC | c.7328G>T p.R2443L | Missense Mutation (SNP) | VAF 83/535 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FN1 | c.2296C>G p.L766V | Missense Mutation (SNP) | VAF 91/596 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- FNDC1 | c.2657C>A p.P886H | Missense Mutation (SNP) | VAF 61/396 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- FTSJ3 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- FUT5 | c.833T>G p.L278R | Missense Mutation (SNP) | VAF 61/710 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- GALNT5 | c.2607G>T p.R869S | Missense Mutation (SNP) | VAF 43/308 reads (14%) | SIFT tolerated (0.94); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GCN1 | c.7307G>T p.G2436V | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.231); called by muse, mutect2
- GCN1 | c.4838T>A p.L1613Q | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GDAP2 | c.646C>G p.Q216E | Missense Mutation (SNP) | VAF 30/209 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GLUD2 | c.72C>A p.N24K | Missense Mutation (SNP) | VAF 40/321 reads (12%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); called by muse, varscan2
- GNG7 | c.124C>A p.H42N | Missense Mutation (SNP) | VAF 43/372 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- GNRHR | c.27G>T p.Q9H | Missense Mutation (SNP) | VAF 139/382 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- GOLGA3 | c.2701C>T p.L901F | Missense Mutation (SNP) | VAF 76/587 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- GOLIM4 | c.1892G>T p.R631M | Missense Mutation (SNP) | VAF 43/393 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- GPATCH8 | c.2114G>A p.G705E | Missense Mutation (SNP) | VAF 80/435 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GPR161 | c.73G>T p.G25C | Missense Mutation (SNP) | VAF 37/324 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- GPR179 | c.808C>A p.Q270K (on ENST00000621958; = p.Q269K on NM_001004334.4) | Missense Mutation (SNP) | VAF 36/181 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- GPR37 | c.1151C>G p.A384G | Missense Mutation (SNP) | VAF 42/319 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- GPT | c.915G>C p.E305D | Missense Mutation (SNP) | VAF 62/328 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GRAMD2B | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- GREB1 | c.2279A>G p.N760S | Missense Mutation (SNP) | VAF 46/194 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- GSX1 | c.430C>A p.L144M | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- GSX1 | c.615G>T p.E205D | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- HECTD4 | c.7189C>T p.R2397W | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HGF | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 77/602 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- HMGA2 | c.283-2A>T p.X95_splice | Splice Site (SNP) | VAF 59/417 reads (14%) | called by muse, mutect2, varscan2
- HOXB3 | c.793C>G p.P265A | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- HSPA1L | c.61G>T p.G21W | Missense Mutation (SNP) | VAF 71/419 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- ICE1 | c.5558G>T p.G1853V | Missense Mutation (SNP) | VAF 45/245 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- IL1R1 | c.1091T>A p.V364E | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- IQGAP2 | c.1486G>T p.D496Y | Missense Mutation (SNP) | VAF 89/224 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- IRF5 | c.1433C>A p.P478H | Missense Mutation (SNP) | VAF 84/533 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- IRGC | c.533G>C p.R178P | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- IRS4 | c.2117G>T p.G706V | Missense Mutation (SNP) | VAF 57/302 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ITIH6 | c.3380G>C p.G1127A | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); called by muse, mutect2
- ITPKC | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 30/210 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); called by muse, mutect2
- JADE2 | c.1697C>G p.S566* | Nonsense Mutation (SNP) | VAF 53/188 reads (28%) | called by muse, mutect2, varscan2
- KALRN | c.319C>G p.L107V | Missense Mutation (SNP) | VAF 64/310 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KCNA5 | c.1672G>T p.G558W | Missense Mutation (SNP) | VAF 49/376 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNMA1 | c.1845C>A p.F615L | Missense Mutation (SNP) | VAF 85/443 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF1A | c.4349A>T p.E1450V (on ENST00000320389 / NM_001379639.1; = p.E1442V on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/357 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- KIF7 | c.478G>T p.G160C | Missense Mutation (SNP) | VAF 44/242 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- KIR2DL3 | c.745G>T p.G249W | Missense Mutation (SNP) | VAF 102/860 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KRT35 | c.253G>T p.G85W | Missense Mutation (SNP) | VAF 92/427 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); called by muse, varscan2
- LGR6 | c.1688G>A p.G563D (on ENST00000367278 / NM_001017403.1; = p.G511D on NM_021636.3) | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- LMO7 | c.3674A>G p.E1225G (on ENST00000357063; = p.E906G on NM_005358.5) | Missense Mutation (SNP) | VAF 43/290 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- MACC1 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 61/342 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- MAG | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 46/298 reads (15%) | called by muse, mutect2, varscan2
- MAGT1 | c.901A>T p.I301L (on ENST00000618282 / NM_001367916.1; = p.I333L on NM_032121.5) | Missense Mutation (SNP) | VAF 13/364 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2
- MAMSTR | c.1172C>T p.P391L (on ENST00000318083 / NM_001130915.2; = p.P288L on NM_182574.2) | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP3K21 | c.1027C>A p.P343T | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAP3K21 | c.2041_2044dup p.N682Rfs*7 | Frame Shift Ins (INS) | VAF 73/262 reads (28%) | called by mutect2, varscan2
- MAP7D1 | c.2407G>T p.G803* | Nonsense Mutation (SNP) | VAF 39/264 reads (15%) | called by muse, mutect2, varscan2
- MAPK7 | c.1181G>A p.G394D | Missense Mutation (SNP) | VAF 71/419 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- MAPT | c.1790C>A p.T597N (on ENST00000262410 / NM_001377265.1; = p.T205N on NM_005910.5) | Missense Mutation (SNP) | VAF 71/404 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MASP1 | c.5G>T p.R2M | Missense Mutation (SNP) | VAF 130/733 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MCHR1 | c.928C>A p.P310T | Missense Mutation (SNP) | VAF 117/604 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MDGA2 | c.247C>T p.L83F | Missense Mutation (SNP) | VAF 106/575 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MEPCE | c.1784G>T p.G595V | Missense Mutation (SNP) | VAF 78/576 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MGAM | c.3453G>T p.W1151C | Missense Mutation (SNP) | VAF 63/377 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MIB1 | c.2597G>A p.C866Y | Missense Mutation (SNP) | VAF 44/248 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MICAL1 | c.239G>T p.R80L | Missense Mutation (SNP) | VAF 39/232 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- MID2 | c.337G>T p.G113W | Missense Mutation (SNP) | VAF 19/296 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- MMP17 | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 51/423 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- MMP8 | c.627C>A p.Y209* | Nonsense Mutation (SNP) | VAF 19/205 reads (9%) | called by muse, mutect2
- MOV10L1 | c.1454+2T>C p.X485_splice | Splice Site (SNP) | VAF 16/84 reads (19%) | called by muse, mutect2, varscan2
- MRPL47 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- MTMR3 | c.1418G>A p.C473Y | Missense Mutation (SNP) | VAF 58/421 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- MUC16 | c.41483C>T p.P13828L | Missense Mutation (SNP) | VAF 65/537 reads (12%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MUC16 | c.39734C>A p.P13245H | Missense Mutation (SNP) | VAF 30/233 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MUC17 | c.11052G>T p.M3684I | Missense Mutation (SNP) | VAF 26/290 reads (9%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.904); called by muse, mutect2
- MUC22 | c.3278A>G p.E1093G | Missense Mutation (SNP) | VAF 115/560 reads (21%) | SIFT tolerated (0.09); called by muse, mutect2, varscan2
- MYH2 | c.88A>G p.R30G | Missense Mutation (SNP) | VAF 126/646 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- NCK2 | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NEDD4 | c.2290C>G p.P764A (on ENST00000508342 / NM_001284338.1; = p.P345A on NM_006154.4) | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- NHSL1 | c.862G>T p.G288W | Missense Mutation (SNP) | VAF 36/206 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NIPBL | c.2624G>T p.G875V | Missense Mutation (SNP) | VAF 53/318 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- NPAS2 | c.1996T>C p.F666L | Missense Mutation (SNP) | VAF 53/264 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NPHS1 | c.3437G>T p.S1146I | Missense Mutation (SNP) | VAF 156/1077 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- NRAP | c.889-1G>T p.X297_splice | Splice Site (SNP) | VAF 38/212 reads (18%) | called by muse, mutect2, varscan2
- NRP1 | c.1962G>T p.W654C | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- NSD1 | c.7063G>T p.G2355W | Missense Mutation (SNP) | VAF 82/462 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- NTRK1 | c.1355-1G>C p.X452_splice | Splice Site (SNP) | VAF 102/641 reads (16%) | called by muse, mutect2, varscan2
- NUDT6 | c.442+1G>T p.X148_splice | Splice Site (SNP) | VAF 58/312 reads (19%) | called by muse, mutect2, varscan2
- NUTM2A | c.1971G>C p.E657D | Missense Mutation (SNP) | VAF 71/537 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- OBSCN | c.6031C>A p.L2011M | Missense Mutation (SNP) | VAF 17/360 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); called by muse, mutect2
- OR1K1 | c.67G>T p.G23* | Nonsense Mutation (SNP) | VAF 39/220 reads (18%) | called by muse, mutect2, varscan2
- OR6K2 | c.863C>A p.P288H | Missense Mutation (SNP) | VAF 44/324 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR6N1 | c.319C>A p.L107I | Missense Mutation (SNP) | VAF 44/246 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR7D4 | c.894G>T p.K298N | Missense Mutation (SNP) | VAF 55/299 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- OSBPL1A | c.583C>T p.L195F | Missense Mutation (SNP) | VAF 14/267 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OXCT1 | c.1087C>A p.L363I | Missense Mutation (SNP) | VAF 62/363 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- PABPN1L | c.196G>T p.G66C | Missense Mutation (SNP) | VAF 45/226 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- PAN2 | c.120C>A p.D40E | Missense Mutation (SNP) | VAF 80/628 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- PCARE | c.1571C>A p.P524Q | Missense Mutation (SNP) | VAF 81/576 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- PCDH12 | c.2714C>T p.A905V | Missense Mutation (SNP) | VAF 137/387 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- PCK1 | c.1370G>T p.G457V | Missense Mutation (SNP) | VAF 81/290 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCLO | c.10685G>C p.G3562A | Missense Mutation (SNP) | VAF 38/278 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- PCNX2 | c.2771G>T p.G924V | Missense Mutation (SNP) | VAF 43/296 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCNX3 | c.4684G>A p.A1562T | Missense Mutation (SNP) | VAF 63/308 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- PDZD7 | c.2147C>A p.P716H | Missense Mutation (SNP) | VAF 43/233 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- PGBD4 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PIWIL2 | c.1622A>G p.K541R | Missense Mutation (SNP) | VAF 46/251 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PKHD1 | c.1208G>T p.S403I | Missense Mutation (SNP) | VAF 81/481 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PLEC | c.8903G>T p.R2968L (on ENST00000322810 / NM_201380.4; = p.R2858L on NM_000445.5) | Missense Mutation (SNP) | VAF 16/440 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2
- PLEKHA8 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 31/222 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- PLEKHA8 | c.1039+1G>A p.X347_splice | Splice Site (SNP) | VAF 33/200 reads (17%) | called by muse, mutect2, varscan2
- PLP1 | c.545C>T p.T182I | Missense Mutation (SNP) | VAF 38/715 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2
- PLXNA3 | c.4527G>T p.K1509N | Missense Mutation (SNP) | VAF 43/336 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- PLXNB3 | c.1755A>T p.Q585H | Missense Mutation (SNP) | VAF 46/257 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PNMT | c.355G>T p.G119W | Missense Mutation (SNP) | VAF 55/287 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PNPLA6 | c.3940G>A p.D1314N (on ENST00000414982 / NM_001166111.2; = p.D1266N on NM_006702.5) | Missense Mutation (SNP) | VAF 62/511 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- PODXL2 | c.1289G>T p.G430V | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- POPDC2 | c.971C>A p.T324N | Missense Mutation (SNP) | VAF 54/397 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- POU3F3 | c.784G>T p.G262W | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- PPM1L | c.802G>C p.G268R | Missense Mutation (SNP) | VAF 29/203 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP1R12B | c.877G>T p.G293C | Missense Mutation (SNP) | VAF 57/284 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- PPP1R1B | c.556G>C p.A186P | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2
- PPP1R21 | c.1476C>G p.D492E | Missense Mutation (SNP) | VAF 27/475 reads (6%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.891); called by muse, mutect2
- PRAME | c.1310C>A p.T437N | Missense Mutation (SNP) | VAF 60/357 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRAMEF18 | c.814C>A p.L272I | Missense Mutation (SNP) | VAF 88/595 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- PRKDC | c.12371G>A p.W4124* | Nonsense Mutation (SNP) | VAF 32/168 reads (19%) | called by muse, mutect2, varscan2
- PTCHD3 | c.794C>A p.P265H | Missense Mutation (SNP) | VAF 92/424 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- PTPN9 | c.712T>A p.Y238N | Missense Mutation (SNP) | VAF 19/260 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.121); called by muse, mutect2
- PUF60 | c.606G>T p.V202= (on ENST00000526683 / NM_001362896.2; = p.V185= on NM_014281.5 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 88/419 reads (21%) | called by muse, mutect2, varscan2
- RAD17 | c.1672C>T p.Q558* (on ENST00000380774 / NM_133339.2; = p.Q547* on NM_002873.1) | Nonsense Mutation (SNP) | VAF 49/342 reads (14%) | called by muse, mutect2, varscan2
- RAD54B | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- RAPGEF5 | c.775G>A p.A259T (on ENST00000401957 / NM_001367602.2; = p.A562T on NM_012294.5) | Missense Mutation (SNP) | VAF 43/420 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RBM27 | c.1874G>T p.G625V | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RECQL4 | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 37/204 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- RFESD | c.383A>G p.N128S | Missense Mutation (SNP) | VAF 53/331 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RHOBTB3 | c.1148_1161+4del p.X383_splice | Splice Site (DEL) | VAF 29/128 reads (23%) | called by mutect2, pindel, varscan2
- RPLP1 | c.146_147delinsGATGTTTGCAA p.X49_splice | Splice Site (INS) | VAF 47/238 reads (20%) | called by mutect2*, pindel, varscan2*
- RTKN2 | c.262G>A p.V88M | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RTL9 | c.176G>T p.G59V | Missense Mutation (SNP) | VAF 11/273 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.513); called by muse, mutect2
- RUNDC3A | c.989C>A p.A330D | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- RUNX3 | c.692C>T p.T231I | Missense Mutation (SNP) | VAF 41/220 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- SATB1 | c.1352G>T p.S451I | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2
- SBNO2 | c.1605G>T p.Q535H | Missense Mutation (SNP) | VAF 41/359 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- SCPEP1 | c.1171C>G p.L391V | Missense Mutation (SNP) | VAF 79/206 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- SELENOV | c.757T>A p.S253T | Missense Mutation (SNP) | VAF 80/733 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEPHS1 | c.485G>A p.G162D | Missense Mutation (SNP) | VAF 49/329 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SERPINA10 | c.641G>T p.R214L | Missense Mutation (SNP) | VAF 86/409 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SERTAD1 | c.352C>T p.L118F | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- SFSWAP | c.281A>G p.N94S | Missense Mutation (SNP) | VAF 40/283 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- SH3BP2 | c.1630C>A p.P544T | Missense Mutation (SNP) | VAF 14/305 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SHANK1 | c.2862del p.F954Lfs*389 | Frame Shift Del (DEL) | VAF 12/90 reads (13%) | called by mutect2, varscan2
- SHISA7 | c.1265G>T p.R422L | Missense Mutation (SNP) | VAF 50/414 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SHROOM4 | c.158G>A p.R53K | Missense Mutation (SNP) | VAF 68/391 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SIGLEC12 | c.1156G>A p.G386S (on ENST00000291707 / NM_053003.4; = p.G268S on NM_033329.2) | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- SLC1A3 | c.1081G>C p.G361R | Missense Mutation (SNP) | VAF 81/427 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC38A7 | c.103C>A p.P35T | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC44A5 | c.201A>T p.R67S | Missense Mutation (SNP) | VAF 24/328 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.089); called by muse, mutect2
- SLC5A8 | c.899C>A p.A300D | Missense Mutation (SNP) | VAF 33/295 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- SMTNL2 | c.1192T>C p.F398L (on ENST00000389313 / NM_001114974.2; = p.F254L on NM_198501.3) | Missense Mutation (SNP) | VAF 43/303 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SNTA1 | c.605C>A p.P202H | Missense Mutation (SNP) | VAF 79/452 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SOX6 | c.485A>G p.K162R | Missense Mutation (SNP) | VAF 37/263 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- SPTA1 | c.5455C>A p.L1819I | Missense Mutation (SNP) | VAF 25/541 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); called by muse, mutect2
- SPTBN5 | c.85C>G p.P29A | Missense Mutation (SNP) | VAF 78/344 reads (23%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SRRT | c.2556-1G>T p.X852_splice | Splice Site (SNP) | VAF 29/177 reads (16%) | called by muse, mutect2, varscan2
- STON2 | c.293C>A p.A98D | Missense Mutation (SNP) | VAF 62/282 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SYNE1 | c.9180T>A p.N3060K (on ENST00000367255 / NM_182961.4; = p.N3067K on NM_033071.3) | Missense Mutation (SNP) | VAF 113/288 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- SYT6 | c.1423G>T p.G475C (on ENST00000610222 / NM_001366225.1; = p.G390C on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 93/326 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TAF5L | c.1406G>A p.G469D | Missense Mutation (SNP) | VAF 65/295 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- TCF4 | c.1487del p.G496Afs*39 | Frame Shift Del (DEL) | VAF 60/386 reads (16%) | called by mutect2, pindel, varscan2
- TCF7L2 | c.63C>G p.F21L | Missense Mutation (SNP) | VAF 17/398 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TESPA1 | c.355C>T p.L119F | Missense Mutation (SNP) | VAF 55/391 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- TF | c.1612G>T p.G538C | Missense Mutation (SNP) | VAF 76/277 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- THSD7A | c.1041G>T p.K347N | Missense Mutation (SNP) | VAF 36/290 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2
- TLR1 | c.1878A>G p.I626M | Missense Mutation (SNP) | VAF 119/389 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TMEM121B | c.112C>A p.R38S | Missense Mutation (SNP) | VAF 81/479 reads (17%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TMEM218 | c.223G>T p.D75Y | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- TMPRSS9 | c.47A>G p.K16R | Missense Mutation (SNP) | VAF 31/225 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- TNFRSF17 | c.85T>A p.S29T | Missense Mutation (SNP) | VAF 42/261 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- TNFRSF25 | c.1171G>T p.G391* | Nonsense Mutation (SNP) | VAF 12/298 reads (4%) | called by muse, mutect2
- TNXB | c.2021G>C p.G674A | Missense Mutation (SNP) | VAF 111/551 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TOPAZ1 | c.4527T>A p.C1509* | Nonsense Mutation (SNP) | VAF 38/219 reads (17%) | called by muse, mutect2, varscan2
- TRIM16L | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 51/208 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- TRPM1 | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 90/456 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TRPV5 | c.1399T>A p.Y467N | Missense Mutation (SNP) | VAF 48/329 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TSPAN16 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.031); called by muse, mutect2
- TTN | c.27629G>T p.W9210L (on ENST00000591111; = p.W8283L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/238 reads (18%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UNC13C | c.5993A>G p.K1998R | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- UNC5D | c.2555A>G p.K852R | Missense Mutation (SNP) | VAF 30/412 reads (7%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.977); called by muse, mutect2
- USP19 | c.1587del p.F530Lfs*11 | Frame Shift Del (DEL) | VAF 41/298 reads (14%) | called by mutect2, pindel, varscan2
- USP36 | c.1123G>C p.G375R | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VAV2 | c.1805C>G p.A602G (on ENST00000371850 / NM_001134398.2; = p.A592G on NM_003371.4) | Missense Mutation (SNP) | VAF 41/264 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- VKORC1 | c.190G>T p.G64W | Missense Mutation (SNP) | VAF 59/235 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDR24 | c.271G>T p.A91S (on ENST00000248142; = p.A29S on NM_032259.4) | Missense Mutation (SNP) | VAF 43/356 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- WNK1 | c.907C>A p.L303I | Missense Mutation (SNP) | VAF 65/500 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WWP1 | c.1387+1G>T p.X463_splice | Splice Site (SNP) | VAF 27/192 reads (14%) | called by muse, mutect2, varscan2
- XPO5 | c.140G>C p.C47S | Missense Mutation (SNP) | VAF 44/252 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZBTB12 | c.944G>T p.G315V | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- ZBTB16 | c.922C>T p.P308S | Missense Mutation (SNP) | VAF 91/467 reads (19%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZCCHC2 | c.1142A>T p.D381V | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZIC1 | c.172T>A p.S58T | Missense Mutation (SNP) | VAF 59/317 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- ZNF229 | c.2001C>G p.C667W | Missense Mutation (SNP) | VAF 57/367 reads (16%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF35 | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 53/244 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- ZNF366 | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF384 | c.551G>T p.G184V | Missense Mutation (SNP) | VAF 17/491 reads (3%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.881); called by muse, mutect2
- ZNF469 | c.1364C>G p.P455R | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ZNF530 | c.1597G>C p.A533P | Missense Mutation (SNP) | VAF 12/350 reads (3%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.5); called by muse, mutect2
- ZNF575 | c.404C>G p.A135G | Missense Mutation (SNP) | VAF 59/537 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ZNF584 | c.796G>T p.G266* | Nonsense Mutation (SNP) | VAF 31/221 reads (14%) | called by muse, mutect2, varscan2
- ZNF705A | c.741G>T p.E247D | Missense Mutation (SNP) | VAF 134/1008 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF804B | c.76G>T p.G26* | Nonsense Mutation (SNP) | VAF 32/253 reads (13%) | called by muse, mutect2, varscan2
- ZXDB | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 68/218 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); called by muse, varscan2
- ABCC2 | c.1776C>A p.P592= | Silent (SNP) | VAF 84/410 reads (20%) | called by muse, mutect2, varscan2
- ADGRG4 | c.8853C>A p.L2951= | Silent (SNP) | VAF 11/78 reads (14%) | called by muse, mutect2
- ADIPOR2 | c.1149G>A p.E383= | Silent (SNP) | VAF 39/251 reads (16%) | catalogued as COSV63946195; called by muse, mutect2, varscan2
- AL121899.2 | c.1341G>T p.V447= | Silent (SNP) | VAF 22/348 reads (6%) | called by muse, mutect2
- ALPG | c.1473C>T p.T491= | Silent (SNP) | VAF 63/890 reads (7%) | called by muse, mutect2
- ANKS1A | c.2745C>A p.P915= | Silent (SNP) | VAF 52/180 reads (29%) | called by muse, mutect2
- ANO5 | c.2253T>C p.F751= | Silent (SNP) | VAF 24/116 reads (21%) | called by muse, varscan2
- APOB | c.3255G>A p.E1085= | Silent (SNP) | VAF 55/306 reads (18%) | catalogued as COSV51932151; called by muse, mutect2, varscan2
- APPL1 | c.2016T>G p.A672= | Silent (SNP) | VAF 41/263 reads (16%) | called by muse, mutect2, varscan2
- ARAP1 | c.2844C>T p.A948= (on ENST00000393609 / NM_001040118.2; = p.A703= on NM_015242.4) | Silent (SNP) | VAF 23/164 reads (14%) | called by muse, mutect2, varscan2
- ASXL1 | c.4185G>T p.L1395= | Silent (SNP) | VAF 49/351 reads (14%) | called by muse, mutect2
- B4GALT6 | c.432G>C p.G144= | Silent (SNP) | VAF 65/397 reads (16%) | called by muse, mutect2, varscan2
- BLNK | c.339C>A p.P113= | Silent (SNP) | VAF 76/368 reads (21%) | catalogued as rs781955654; called by muse, mutect2, varscan2
- C11orf45 | c.141G>A p.R47= | Silent (SNP) | VAF 29/154 reads (19%) | catalogued as rs768859509; called by muse, mutect2, varscan2
- C2CD6 | c.1278T>A p.T426= | Silent (SNP) | VAF 51/249 reads (20%) | called by muse, mutect2, varscan2
- C4orf54 | c.2337C>T p.P779= | Silent (SNP) | VAF 84/220 reads (38%) | catalogued as rs1450567350; called by muse, mutect2, varscan2
- CACNA1C | c.2475C>T p.D825= | Silent (SNP) | VAF 20/208 reads (10%) | called by muse, mutect2
- CACNA1F | c.1902G>A p.K634= | Silent (SNP) | VAF 94/515 reads (18%) | called by muse, mutect2, varscan2
- CACNA1S | c.1839G>T p.G613= | Silent (SNP) | VAF 28/170 reads (16%) | called by muse, mutect2, varscan2
- CAPN12 | c.555C>T p.Y185= | Silent (SNP) | VAF 79/275 reads (29%) | catalogued as rs751875254, COSV61018937; called by muse, mutect2, varscan2
- CARD6 | c.273C>T p.G91= | Silent (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- CD163L1 | c.2913G>T p.G971= | Silent (SNP) | VAF 61/571 reads (11%) | called by muse, mutect2, varscan2
- CD248 | c.1446C>A p.I482= | Silent (SNP) | VAF 61/421 reads (14%) | called by muse, mutect2, varscan2
- CDH18 | c.195A>G p.E65= | Silent (SNP) | VAF 55/296 reads (19%) | catalogued as COSV56953393; called by muse, mutect2, varscan2
- CDH22 | c.1242C>T p.G414= | Silent (SNP) | VAF 92/238 reads (39%) | catalogued as rs1420297759; called by muse, mutect2, varscan2
- CDH22 | c.36G>T p.A12= | Silent (SNP) | VAF 79/464 reads (17%) | called by muse, varscan2
- CDH23 | c.4857C>T p.H1619= | Silent (SNP) | VAF 106/282 reads (38%) | catalogued as rs369817589; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CEBPD | c.507G>A p.R169= | Silent (SNP) | VAF 14/74 reads (19%) | called by muse, mutect2, varscan2
- CEP68 | c.2064G>A p.K688= | Silent (SNP) | VAF 11/119 reads (9%) | called by muse, mutect2
- CHD4 | c.2136C>G p.T712= (on ENST00000357008 / NM_001363606.2; = p.T725= on NM_001273.5) | Silent (SNP) | VAF 42/289 reads (15%) | catalogued as rs751476341; called by muse, mutect2, varscan2
- CHFR | c.12C>G p.P4= | Silent (SNP) | VAF 33/216 reads (15%) | called by muse, mutect2, varscan2
- CLCA4 | c.63T>C p.T21= | Silent (SNP) | VAF 75/216 reads (35%) | catalogued as rs1006398304; called by muse, mutect2, varscan2
- CNOT3 | c.1698C>A p.T566= | Silent (SNP) | VAF 61/425 reads (14%) | called by muse, mutect2, varscan2
- COL4A4 | c.4650C>A p.P1550= | Silent (SNP) | VAF 24/166 reads (14%) | catalogued as rs762516627; called by muse, mutect2, varscan2
- CSF3R | c.1668G>A p.K556= | Silent (SNP) | VAF 40/152 reads (26%) | called by muse, mutect2, varscan2
- CSMD1 | c.8058G>A p.P2686= (on ENST00000520002; = p.P2685= on NM_033225.6) | Silent (SNP) | VAF 64/141 reads (45%) | catalogued as rs376009667; called by muse, mutect2, varscan2
- CTAG2 | c.471C>T p.S157= | Silent (SNP) | VAF 69/238 reads (29%) | catalogued as rs1557241414, COSV55996980; called by muse, mutect2, varscan2
- CYP27A1 | c.870C>T p.L290= | Silent (SNP) | VAF 126/367 reads (34%) | catalogued as rs202136743; called by muse, mutect2, varscan2
- CYTH1 | c.1050G>T p.G350= | Silent (SNP) | VAF 50/279 reads (18%) | called by muse, mutect2, varscan2
- DCLK1 | c.99G>A p.P33= | Silent (SNP) | VAF 44/309 reads (14%) | catalogued as rs754667282; called by muse, mutect2, varscan2
- DMPK | c.462G>T p.G154= | Silent (SNP) | VAF 49/304 reads (16%) | catalogued as rs754963585; called by muse, mutect2, varscan2
- DOLK | c.1275C>A p.P425= | Silent (SNP) | VAF 73/417 reads (18%) | called by muse, mutect2, varscan2
- DQX1 | c.1123C>A p.R375= | Silent (SNP) | VAF 51/286 reads (18%) | catalogued as rs150420269; called by muse, mutect2, varscan2
- DST | c.16572G>T p.L5524= (on ENST00000361203 / NM_001374722.1; = p.L3112= on NM_015548.5) | Silent (SNP) | VAF 29/205 reads (14%) | catalogued as rs748852526; called by muse, mutect2, varscan2
- DYNC1I2 | c.546A>G p.K182= | Silent (SNP) | VAF 16/188 reads (9%) | called by muse, mutect2
- ELOA2 | c.1245C>T p.N415= | Silent (SNP) | VAF 222/645 reads (34%) | catalogued as rs767658717; called by muse, mutect2, varscan2
- EPHA5 | c.2124C>T p.T708= | Silent (SNP) | VAF 43/294 reads (15%) | catalogued as COSV56674703; called by muse, mutect2, varscan2
- ERAS | c.531C>T p.F177= | Silent (SNP) | VAF 62/184 reads (34%) | catalogued as rs782348492, COSV54432734; called by muse, mutect2, varscan2
- ERC2 | c.1104G>A p.P368= | Silent (SNP) | VAF 143/358 reads (40%) | catalogued as rs559591672, COSV99883835; called by muse, mutect2, varscan2
- EVPL | c.5820G>A p.L1940= | Silent (SNP) | VAF 21/114 reads (18%) | called by muse, mutect2, varscan2
- F5 | c.4263C>A p.S1421= | Silent (SNP) | VAF 54/315 reads (17%) | called by muse, mutect2, varscan2
- FAM189A1 | c.462G>C p.G154= | Silent (SNP) | VAF 32/246 reads (13%) | called by muse, mutect2, varscan2
- FARP2 | c.2137C>T p.L713= | Silent (SNP) | VAF 21/92 reads (23%) | called by muse, mutect2, varscan2
- FIG4 | c.1692C>G p.T564= | Silent (SNP) | VAF 67/274 reads (24%) | catalogued as rs1340609696; called by muse, mutect2, varscan2
- FLG2 | c.4305G>T p.G1435= | Silent (SNP) | VAF 122/683 reads (18%) | catalogued as rs1255564072; called by muse, mutect2, varscan2
- FLNC | c.8106G>C p.G2702= | Silent (SNP) | VAF 44/334 reads (13%) | called by muse, mutect2, varscan2
- FOXF1 | c.180C>T p.A60= | Silent (SNP) | VAF 159/480 reads (33%) | catalogued as rs891128602; called by muse, mutect2, varscan2
- FRMPD3 | c.2745C>A p.S915= | Silent (SNP) | VAF 49/252 reads (19%) | called by muse, mutect2, varscan2
- GATAD2B | c.282G>A p.R94= | Silent (SNP) | VAF 54/294 reads (18%) | called by muse, mutect2, varscan2
- GBF1 | c.570G>A p.Q190= | Silent (SNP) | VAF 11/146 reads (8%) | called by muse, mutect2
- GBP6 | c.30C>A p.P10= | Silent (SNP) | VAF 40/107 reads (37%) | called by muse, mutect2
- GDF6 | c.552C>A p.L184= | Silent (SNP) | VAF 66/295 reads (22%) | catalogued as COSV54624510; called by muse, mutect2, varscan2
- GFRA4 | c.276G>A p.A92= | Silent (SNP) | VAF 51/260 reads (20%) | called by muse, mutect2, varscan2
- GRIN2B | c.3516C>A p.P1172= | Silent (SNP) | VAF 78/595 reads (13%) | called by muse, mutect2
- GSC2 | c.126G>A p.P42= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs1555918176; called by muse, mutect2, varscan2
- HP1BP3 | c.1419G>A p.K473= | Silent (SNP) | VAF 19/208 reads (9%) | called by muse, mutect2
- IL22 | c.297C>G p.T99= | Silent (SNP) | VAF 49/361 reads (14%) | catalogued as COSV60160629; called by muse, mutect2, varscan2
- ITGA5 | c.3132A>T p.P1044= | Silent (SNP) | VAF 55/392 reads (14%) | called by muse, mutect2, varscan2
- KCNA1 | c.723C>T p.F241= | Silent (SNP) | VAF 435/810 reads (54%) | catalogued as rs147731985, COSV66836616; called by muse, mutect2, varscan2
- KCNG2 | c.117C>A p.P39= | Silent (SNP) | VAF 22/118 reads (19%) | called by muse, mutect2, varscan2
- KIAA0232 | c.984G>C p.R328= | Silent (SNP) | VAF 62/378 reads (16%) | called by muse, mutect2, varscan2
- KRT83 | c.285C>A p.P95= | Silent (SNP) | VAF 164/1170 reads (14%) | called by muse, varscan2
- L3MBTL2 | c.1446C>T p.H482= | Silent (SNP) | VAF 60/322 reads (19%) | catalogued as rs764759330; called by muse, mutect2, varscan2
- LAMA5 | c.9144G>T p.V3048= | Silent (SNP) | VAF 118/532 reads (22%) | called by muse, mutect2, varscan2
- LHFPL5 | c.303G>T p.V101= | Silent (SNP) | VAF 142/777 reads (18%) | catalogued as COSV100798962; called by muse, mutect2, varscan2
- LPIN1 | c.1332C>T p.S444= | Silent (SNP) | VAF 12/416 reads (3%) | called by muse, mutect2
- LRP1B | c.1452G>T p.G484= | Silent (SNP) | VAF 34/219 reads (16%) | catalogued as rs775767827; called by muse, mutect2, varscan2
- LRRTM4 | c.159A>C p.A53= | Silent (SNP) | VAF 78/370 reads (21%) | catalogued as COSV69140781; called by muse, mutect2, varscan2
- LTBP3 | c.1815C>T p.Y605= | Silent (SNP) | VAF 149/736 reads (20%) | catalogued as COSV57243009; called by muse, mutect2, varscan2
- MAP4 | c.2253C>G p.A751= | Silent (SNP) | VAF 58/335 reads (17%) | called by muse, mutect2, varscan2
- MBD3L2 | c.423C>T p.P141= | Silent (SNP) | VAF 64/1770 reads (4%) | catalogued as rs1196457169, COSV61588897; called by muse, mutect2
- MBD5 | c.3963C>A p.S1321= | Silent (SNP) | VAF 83/505 reads (16%) | called by muse, mutect2, varscan2
- MGAM2 | c.4374A>T p.R1458= | Silent (SNP) | VAF 73/612 reads (12%) | called by muse, mutect2, varscan2
- MIB2 | c.1686G>A p.R562= | Silent (SNP) | VAF 45/232 reads (19%) | catalogued as COSV100598932; called by muse, mutect2, varscan2
- MICAL3 | c.4740G>A p.R1580= | Silent (SNP) | VAF 87/502 reads (17%) | called by muse, mutect2, varscan2
- MINAR1 | c.1428C>A p.T476= | Silent (SNP) | VAF 25/157 reads (16%) | called by muse, mutect2, varscan2
- MMAA | c.381A>G p.L127= | Silent (SNP) | VAF 29/156 reads (19%) | catalogued as rs990266810; called by muse, mutect2, varscan2
- MPDZ | c.525G>T p.V175= | Silent (SNP) | VAF 29/143 reads (20%) | called by muse, mutect2, varscan2
- MUC16 | c.19638C>A p.T6546= | Silent (SNP) | VAF 39/315 reads (12%) | called by muse, mutect2, varscan2
- NID1 | c.3189G>A p.L1063= | Silent (SNP) | VAF 28/156 reads (18%) | catalogued as rs749116198; called by muse, mutect2, varscan2
- NKAIN4 | c.288G>C p.L96= | Silent (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- NRXN2 | c.1296C>T p.S432= | Silent (SNP) | VAF 88/503 reads (17%) | called by muse, mutect2, varscan2
- NUP214 | c.2820C>A p.S940= | Silent (SNP) | VAF 69/356 reads (19%) | called by muse, mutect2, varscan2
- OR52L1 | c.511T>C p.L171= | Silent (SNP) | VAF 72/311 reads (23%) | called by muse, mutect2
- OR56A3 | c.717A>T p.A239= | Silent (SNP) | VAF 27/211 reads (13%) | called by muse, mutect2, varscan2
- OR8D1 | c.171C>G p.T57= | Silent (SNP) | VAF 54/292 reads (18%) | catalogued as COSV100766690; called by muse, mutect2, varscan2
- PCDHB5 | c.714C>T p.N238= | Silent (SNP) | VAF 102/303 reads (34%) | catalogued as rs1320435155, COSV50647548; called by muse, mutect2, varscan2
- PDYN | c.519A>G p.K173= | Silent (SNP) | VAF 102/648 reads (16%) | called by muse, mutect2, varscan2
- PIP5K1A | c.864A>G p.Q288= (on ENST00000368888 / NM_001135638.2; = p.Q275= on NM_003557.3) | Silent (SNP) | VAF 81/392 reads (21%) | called by muse, mutect2, varscan2
- POPDC2 | c.972C>A p.T324= | Silent (SNP) | VAF 53/398 reads (13%) | called by muse, mutect2, varscan2
- POU3F1 | c.48C>A p.A16= | Silent (SNP) | VAF 24/104 reads (23%) | called by muse, varscan2
- PPT2 | c.30C>A p.P10= | Silent (SNP) | VAF 27/168 reads (16%) | catalogued as COSV52999201; called by muse, mutect2, varscan2
- PRAME | c.1149G>T p.L383= | Silent (SNP) | VAF 83/214 reads (39%) | called by muse, mutect2, varscan2
- PRPF6 | c.954G>T p.L318= | Silent (SNP) | VAF 71/526 reads (13%) | called by muse, mutect2, varscan2
- PTCHD1 | c.2637C>T p.T879= | Silent (SNP) | VAF 27/198 reads (14%) | called by muse, mutect2, varscan2
- PZP | c.1101G>C p.L367= | Silent (SNP) | VAF 8/143 reads (6%) | called by muse, mutect2
- RAB3IP | c.1167C>T p.C389= (on ENST00000550536 / NM_175623.4; = p.C373= on NM_022456.5) | Silent (SNP) | VAF 166/290 reads (57%) | catalogued as rs759943167, COSV56086458; called by muse, mutect2, varscan2
- RALGAPA2 | c.2544C>T p.N848= | Silent (SNP) | VAF 21/202 reads (10%) | called by muse, mutect2, varscan2
- RAPGEF5 | c.228C>A p.T76= (on ENST00000401957 / NM_001367602.2; = p.T379= on NM_012294.5) | Silent (SNP) | VAF 95/579 reads (16%) | catalogued as rs1312999080; called by muse, mutect2, varscan2
- RASA1 | c.2112G>A p.G704= | Silent (SNP) | VAF 58/371 reads (16%) | catalogued as rs374292148; called by muse, mutect2, varscan2
- RASGRF2 | c.2325G>A p.A775= | Silent (SNP) | VAF 175/469 reads (37%) | catalogued as rs1224821048, COSV54129465, COSV54129950; called by muse, mutect2, varscan2
- RELB | c.891C>A p.S297= | Silent (SNP) | VAF 33/253 reads (13%) | called by muse, mutect2, varscan2
- RPS6KA4 | c.1620C>T p.D540= | Silent (SNP) | VAF 17/191 reads (9%) | called by muse, mutect2
- RUFY1 | c.1542G>T p.G514= | Silent (SNP) | VAF 62/309 reads (20%) | called by muse, mutect2, varscan2
- SAMD4A | c.654C>T p.P218= | Silent (SNP) | VAF 57/324 reads (18%) | called by muse, mutect2, varscan2
- SBK1 | c.864G>T p.A288= | Silent (SNP) | VAF 45/232 reads (19%) | called by muse, mutect2, varscan2
- SCAPER | c.1755A>G p.E585= | Silent (SNP) | VAF 46/191 reads (24%) | catalogued as rs1463120397; called by muse, mutect2, varscan2
- SDR39U1 | c.546C>A p.P182= | Silent (SNP) | VAF 62/341 reads (18%) | called by muse, mutect2, varscan2
- SEMA6C | c.1794C>G p.S598= | Silent (SNP) | VAF 34/178 reads (19%) | called by mutect2, varscan2
- SETDB1 | c.618C>T p.G206= | Silent (SNP) | VAF 21/135 reads (16%) | called by muse, mutect2, varscan2
- SH2D3C | c.1440G>A p.P480= (on ENST00000314830 / NM_170600.3; = p.P323= on NM_005489.4) | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as rs199821667, COSV59129265; called by muse, mutect2, varscan2
- SHROOM2 | c.663C>T p.D221= | Silent (SNP) | VAF 106/551 reads (19%) | called by muse, mutect2, varscan2
- SLC13A5 | c.663C>T p.T221= | Silent (SNP) | VAF 107/331 reads (32%) | catalogued as rs373831482; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC22A31 | c.906C>T p.A302= | Silent (SNP) | VAF 108/290 reads (37%) | catalogued as rs769295753; called by muse, mutect2, varscan2
- SLC47A2 | c.1737G>T p.G579= | Silent (SNP) | VAF 117/493 reads (24%) | catalogued as rs145748133; called by muse, mutect2, varscan2
- SLFN12 | c.1014C>A p.I338= | Silent (SNP) | VAF 28/172 reads (16%) | catalogued as COSV59225612; called by muse, varscan2
- SMG9 | c.417G>T p.G139= | Silent (SNP) | VAF 49/398 reads (12%) | catalogued as COSV99526620; called by muse, mutect2, varscan2
- SOX1 | c.759G>C p.A253= | Silent (SNP) | VAF 51/382 reads (13%) | called by muse, mutect2, varscan2
- ST8SIA5 | c.516C>T p.I172= | Silent (SNP) | VAF 14/479 reads (3%) | called by muse, mutect2
- STIM1 | c.1197C>T p.S399= | Silent (SNP) | VAF 26/156 reads (17%) | called by muse, mutect2, varscan2
- SYNE1 | c.2832G>A p.R944= (on ENST00000367255 / NM_182961.4; = p.R951= on NM_033071.3) | Silent (SNP) | VAF 43/238 reads (18%) | catalogued as COSV55027705; called by muse, mutect2, varscan2
- TBXA2R | c.615C>A p.G205= | Silent (SNP) | VAF 145/963 reads (15%) | called by muse, mutect2, varscan2
- TCTN2 | c.768C>A p.S256= | Silent (SNP) | VAF 39/285 reads (14%) | called by muse, mutect2, varscan2
- TFCP2 | c.747G>A p.T249= | Silent (SNP) | VAF 45/432 reads (10%) | catalogued as rs760205763; called by muse, mutect2, varscan2
- TNIK | c.3468A>G p.K1156= | Silent (SNP) | VAF 54/157 reads (34%) | catalogued as rs1388491392; called by muse, mutect2, varscan2
- TNN | c.2457G>A p.P819= | Silent (SNP) | VAF 100/343 reads (29%) | catalogued as rs370444325; called by muse, mutect2, varscan2
- TOP1 | c.795C>T p.D265= | Silent (SNP) | VAF 29/207 reads (14%) | called by muse, mutect2, varscan2
- TPP2 | c.3237G>C p.A1079= | Silent (SNP) | VAF 41/247 reads (17%) | catalogued as rs961666776, COSV65753867; called by muse, mutect2, varscan2
- TRMT44 | c.198G>A p.E66= | Silent (SNP) | VAF 59/152 reads (39%) | catalogued as rs1207453129; called by muse, mutect2, varscan2
- TSKS | c.918G>T p.G306= | Silent (SNP) | VAF 58/426 reads (14%) | catalogued as COSV55879192; called by muse, mutect2, varscan2
- TTC28 | c.1287G>A p.E429= | Silent (SNP) | VAF 142/421 reads (34%) | called by muse, mutect2, varscan2
- TYW5 | c.84A>G p.K28= | Silent (SNP) | VAF 66/285 reads (23%) | called by muse, mutect2, varscan2
- UHRF1 | c.1092G>T p.R364= (on ENST00000612630 / NM_001290050.1; = p.R377= on NM_013282.4) | Silent (SNP) | VAF 49/385 reads (13%) | called by muse, mutect2, varscan2
- UMOD | c.1164C>A p.P388= | Silent (SNP) | VAF 46/277 reads (17%) | called by muse, mutect2, varscan2
- USP31 | c.1428T>C p.P476= | Silent (SNP) | VAF 51/273 reads (19%) | called by muse, mutect2, varscan2
- VARS2 | c.318C>A p.P106= | Silent (SNP) | VAF 33/215 reads (15%) | catalogued as COSV52557427, COSV99462051; called by muse, mutect2, varscan2
- VIM | c.15C>A p.S5= | Silent (SNP) | VAF 29/242 reads (12%) | catalogued as CD162365; called by muse, mutect2, varscan2
- VSIG1 | c.718T>C p.L240= | Silent (SNP) | VAF 44/238 reads (18%) | called by muse, mutect2, varscan2
- WNK1 | c.3417T>C p.T1139= (on ENST00000315939 / NM_018979.4; = p.T892= on NM_014823.3) | Silent (SNP) | VAF 73/548 reads (13%) | called by muse, mutect2, varscan2
- YWHAH | c.6G>T p.G2= | Silent (SNP) | VAF 45/292 reads (15%) | called by muse, mutect2, varscan2
- ZC3HAV1 | c.853C>T p.L285= | Silent (SNP) | VAF 71/509 reads (14%) | called by muse, mutect2, varscan2
- ZNF845 | c.171G>A p.E57= | Silent (SNP) | VAF 24/215 reads (11%) | called by muse, varscan2
- ZNF865 | c.861C>T p.P287= | Silent (SNP) | VAF 32/210 reads (15%) | catalogued as rs1462414810; called by muse, mutect2, varscan2
- AC034105.1 | n.50G>A | RNA (SNP) | VAF 12/307 reads (4%) | called by muse, mutect2
- AC244258.1 | n.364G>T | RNA (SNP) | VAF 33/186 reads (18%) | called by muse, mutect2, varscan2
- ACBD5 | chr10:27197161 C>A | 3'Flank (SNP) | VAF 14/42 reads (33%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73852087 C>T | 3'Flank (SNP) | VAF 123/731 reads (17%) | called by muse, mutect2, varscan2
- AL645929.2 | chr6:29888525 C>A | 5'Flank (SNP) | VAF 47/291 reads (16%) | called by muse, mutect2, varscan2
- ALDH3A1 | c.394+240G>T | Intron (SNP) | VAF 22/128 reads (17%) | called by muse, mutect2, varscan2
- AMFR | c.*412G>A | 3'UTR (SNP) | VAF 34/126 reads (27%) | catalogued as rs573375786; called by muse, mutect2, varscan2
- ASPG | c.-11C>A | 5'UTR (SNP) | VAF 63/275 reads (23%) | called by muse, mutect2, varscan2
- ATG2A | chr11:64891443 G>T | 3'Flank (SNP) | VAF 28/122 reads (23%) | called by muse, mutect2, varscan2
- ATP2A2 | c.-42G>A | 5'UTR (SNP) | VAF 18/89 reads (20%) | catalogued as rs1465529079; called by muse, mutect2, varscan2
- BLK | c.1030-74G>T | Intron (SNP) | VAF 30/222 reads (14%) | called by muse, mutect2, varscan2
- CACNB4 | c.1116+28_1116+30del | Intron (DEL) | VAF 38/96 reads (40%) | called by pindel, varscan2
- CCDC102B | c.1263+189C>A | Intron (SNP) | VAF 23/250 reads (9%) | catalogued as COSV100103810; called by muse, mutect2
- CHRNA2 | c.295-24C>T | Intron (SNP) | VAF 64/437 reads (15%) | called by muse, mutect2, varscan2
- CMAHP | n.993C>T | RNA (SNP) | VAF 12/216 reads (6%) | catalogued as rs1417238898; called by muse, mutect2
- COX14 | chr12:50123566 C>T | 3'Flank (SNP) | VAF 226/428 reads (53%) | catalogued as rs1378780531; called by muse, mutect2, varscan2
- CYBA | c.369+906G>C | Intron (SNP) | VAF 50/329 reads (15%) | called by muse, mutect2, varscan2
- CYLC2 | c.-16G>T | 5'UTR (SNP) | VAF 14/254 reads (6%) | called by muse, mutect2
- CYP2A7P2 | n.588C>G | RNA (SNP) | VAF 22/228 reads (10%) | called by muse, mutect2
- CYP2C9 | c.*526G>A | 3'UTR (SNP) | VAF 15/63 reads (24%) | catalogued as rs985311781; called by muse, mutect2, varscan2
- DLG2 | c.205-65794G>A | Intron (SNP) | VAF 103/258 reads (40%) | catalogued as rs552998302, COSV54619672; called by muse, mutect2, varscan2
- DNMT1 | c.3475+35G>C | Intron (SNP) | VAF 95/640 reads (15%) | called by muse, mutect2, varscan2
- DOCK2 | c.2799+34436G>T | Intron (SNP) | VAF 58/345 reads (17%) | called by muse, mutect2, varscan2
- ERCC2 | c.1119-47G>T | Intron (SNP) | VAF 35/189 reads (19%) | called by muse, mutect2, varscan2
- FLT4 | c.*8C>T | 3'UTR (SNP) | VAF 123/352 reads (35%) | catalogued as rs190791214, COSV99987271; called by muse, mutect2, varscan2
- GABRE | c.784+210G>T | Intron (SNP) | VAF 66/213 reads (31%) | called by muse, mutect2, varscan2
- GGTLC2 | chr22:22643620 C>T | 5'Flank (SNP) | VAF 44/222 reads (20%) | called by mutect2, varscan2
- GK | c.-62C>A | 5'UTR (SNP) | VAF 74/376 reads (20%) | called by muse, mutect2, varscan2
- GORASP1 | c.916+180G>C | Intron (SNP) | VAF 48/330 reads (15%) | called by muse, mutect2, varscan2
- GSTO2 | c.468+6513A>G | Intron (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2, varscan2
- HADH | c.133-4981G>A | Intron (SNP) | VAF 121/297 reads (41%) | catalogued as rs1329999456; called by muse, mutect2, varscan2
- HYOU1 | c.*3C>G | 3'UTR (SNP) | VAF 49/235 reads (21%) | called by muse, mutect2, varscan2
- KCND1 | c.1368+9G>C | Intron (SNP) | VAF 12/227 reads (5%) | called by muse, mutect2
- LRBA | c.6363+8783C>T | Intron (SNP) | VAF 19/365 reads (5%) | called by muse, mutect2
- LRRC23 | c.*91A>G | 3'UTR (SNP) | VAF 18/147 reads (12%) | called by muse, mutect2, varscan2
- LRRFIP1 | c.250-9067G>A | Intron (SNP) | VAF 61/291 reads (21%) | called by muse, mutect2, varscan2
- MAGEB16 | c.-25C>T | 5'UTR (SNP) | VAF 17/111 reads (15%) | called by muse, mutect2
- MAP3K12 | c.138-15G>T | Intron (SNP) | VAF 91/582 reads (16%) | called by muse, mutect2, varscan2
- MASP2 | c.544+20C>A | Intron (SNP) | VAF 116/676 reads (17%) | catalogued as COSV101280175; called by muse, mutect2, varscan2
- MCRIP1 | c.*12C>G | 3'UTR (SNP) | VAF 49/291 reads (17%) | called by muse, mutect2, varscan2
- MIR521-1 | n.56C>A | RNA (SNP) | VAF 61/301 reads (20%) | called by muse, mutect2, varscan2
- MIR654 | n.63C>T | RNA (SNP) | VAF 56/361 reads (16%) | called by muse, mutect2, varscan2
- MIR920 | n.53G>T | RNA (SNP) | VAF 33/272 reads (12%) | called by muse, mutect2, varscan2
- MMP17 | c.968+28C>T | Intron (SNP) | VAF 190/365 reads (52%) | catalogued as rs979007463, COSV62180959; called by muse, mutect2, varscan2
- MOCS1 | c.*720C>A | 3'UTR (SNP) | VAF 107/589 reads (18%) | called by muse, mutect2, varscan2
- MYLK3 | c.2115-833G>A | Intron (SNP) | VAF 38/114 reads (33%) | catalogued as rs1377070022; called by muse, mutect2, varscan2
- MYO18A | c.1000-6117C>A | Intron (SNP) | VAF 37/175 reads (21%) | catalogued as rs1320421955; called by muse, mutect2, varscan2
- NHLH2 | c.-8-17T>G | Intron (SNP) | VAF 100/484 reads (21%) | catalogued as rs1324668797; called by muse, mutect2, varscan2
- NISCH | c.1528+84G>A | Intron (SNP) | VAF 40/194 reads (21%) | catalogued as COSV61902972; called by muse, mutect2, varscan2
- NRK | c.4354-893T>A | Intron (SNP) | VAF 52/319 reads (16%) | called by muse, mutect2, varscan2
- OBSCN | c.988+58G>T | Intron (SNP) | VAF 50/325 reads (15%) | called by muse, mutect2, varscan2
- OBSCN | c.18662-2156G>T | Intron (SNP) | VAF 53/234 reads (23%) | called by muse, mutect2, varscan2
- OGFOD2 | c.403+46C>A | Intron (SNP) | VAF 50/458 reads (11%) | called by muse, mutect2, varscan2
- PCDH18 | c.-202G>C | 5'UTR (SNP) | VAF 34/256 reads (13%) | called by muse, mutect2, varscan2
- PHKA1 | c.3072+2166G>A | Intron (SNP) | VAF 13/226 reads (6%) | catalogued as rs781940172; called by muse, mutect2
- PITX3 | c.*8C>A | 3'UTR (SNP) | VAF 32/152 reads (21%) | catalogued as COSV100892799; called by muse, mutect2, varscan2
- PRR3 | c.169+13G>A | Intron (SNP) | VAF 93/252 reads (37%) | called by muse, mutect2, varscan2
- PSIP1 | c.456+18C>T | Intron (SNP) | VAF 43/132 reads (33%) | called by muse, mutect2, varscan2
- PTGER3 | c.*24-16397A>T | Intron (SNP) | VAF 39/165 reads (24%) | catalogued as rs774141890; called by muse, mutect2, varscan2
- RIPOR1 | c.-20G>T | 5'UTR (SNP) | VAF 31/158 reads (20%) | called by muse, mutect2
- RND2 | c.-15C>A | 5'UTR (SNP) | VAF 50/194 reads (26%) | called by muse, mutect2, varscan2
- SCLT1 | c.235-1103C>T | Intron (SNP) | VAF 13/98 reads (13%) | called by muse, mutect2, varscan2
- SEPTIN1 | c.581+9G>T | Intron (SNP) | VAF 68/244 reads (28%) | called by muse, mutect2, varscan2
- SLC16A2 | c.-131C>T | 5'UTR (SNP) | VAF 162/394 reads (41%) | called by muse, mutect2, varscan2
- SLC35A1 | chr6:87472940 C>T | 5'Flank (SNP) | VAF 3/24 reads (13%) | catalogued as rs1048690052; called by muse, mutect2
- SLC5A5 | c.-96C>G | 5'UTR (SNP) | VAF 15/108 reads (14%) | called by muse, mutect2, varscan2
- SPOCD1 | c.2535-106C>G | Intron (SNP) | VAF 12/77 reads (16%) | called by muse, mutect2, varscan2
- SSR2 | c.155+771G>T | Intron (SNP) | VAF 15/119 reads (13%) | called by muse, mutect2, varscan2
- TCP11X2 | c.710-60C>T | Intron (SNP) | VAF 33/424 reads (8%) | called by muse, mutect2
- TGFBR3 | c.*250T>C | 3'UTR (SNP) | VAF 59/291 reads (20%) | called by muse, mutect2, varscan2
- TIA1 | c.583+74G>C | Intron (SNP) | VAF 47/267 reads (18%) | called by muse, mutect2, varscan2
- TMEM105 | n.818G>T | RNA (SNP) | VAF 14/340 reads (4%) | catalogued as COSV59655276; called by muse, mutect2
- TMEM52 | c.170+43G>T | Intron (SNP) | VAF 28/123 reads (23%) | called by muse, mutect2, varscan2
- TUBB8P7 | n.1185C>A | RNA (SNP) | VAF 72/568 reads (13%) | called by muse, varscan2
- VAMP1 | c.*518C>A | 3'UTR (SNP) | VAF 48/350 reads (14%) | called by muse, mutect2, varscan2
- WT1 | chr11:32439651 C>T | 5'Flank (SNP) | VAF 49/278 reads (18%) | catalogued as rs1176728184; called by muse, mutect2, varscan2
- ZIC4 | c.-16+867A>G | Intron (SNP) | VAF 84/441 reads (19%) | called by muse, mutect2, varscan2
- ZNF354A | c.161-720C>A | Intron (SNP) | VAF 45/238 reads (19%) | catalogued as rs1324942178; called by muse, mutect2, varscan2
- ZNF548 | c.16-2911G>T | Intron (SNP) | VAF 20/623 reads (3%) | called by muse, mutect2
- ZNFX1 | c.2665-14A>C | Intron (SNP) | VAF 40/143 reads (28%) | called by muse, mutect2, varscan2
